TCGA case TCGA-IB-7887 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe699c36-82ef-45dd-b636-8c18a9ef6c76

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 62 years; Vital status: Dead; Days to death: 110 days; Cause of death: Cancer Related; Cause of death source: Death Certificate.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 62.9 years (22,990 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 110 days; Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 8; Tumor largest dimension diameter: 5.5 cm.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 110.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-7887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-IB-7887-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20.
  Slide TCGA-IB-7887-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 25.
- Sample TCGA-IB-7887-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-7887-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Anatomic organ subdivision: Head of Pancreas; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 2; Alcohol history documented: No; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Lost to follow-up: No; Cause of death: Pancreatic Cancer; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 110 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 110 days; progression-free interval: no event (censored), 110 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-7887-01A-11D-2153-01): tumor purity 0.34, ploidy 1.78, whole-genome doublings 0.
